Surgical pathology report (de-identified scan), TCGA case TCGA-24-1417, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1417-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Physician(s):

DIAGNOSIS:

OMENTUM, EXCISION (FS1)

- HIGH GRADE PAPILLARY SEROUS CARCINOMA (2.2 CM)

OVARY, LEFT, EXCISION

- HIGH GRADE PAPILLARY SEROUS CARCINOMA (6.0 CM), INVOLVING OVARIAN PARENCHYMA AND SURFACE

FALLOPIAN TUBE, LEFT, EXCISION

- HIGH GRADE SEROUS CARCINOMA INVOLVING THE PARATUBAL SOFT TISSUE

OVARY, RIGHT, EXCISION

- HIGH GRADE PAPILLARY SEROUS CARCINOMA (9.5 CM), INVOLVING OVARIAN PARENCHYMA AND SURFACE

FALLOPIAN TUBE, RIGHT, EXCISION

- HIGH GRADE SEROUS CARCINOMA INVOLVING PERITUBAL SOFT TISSUE

UTERUS, CERVIX, EXCISION

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, EXCISION

- ENDOMETRIAL ATYPIA AND CURETTAGE EFFECT(SEE COMMENT)

UTERUS, MYOMETRIUM, EXCISION

- HIGH GRADE PAPILLARY SEROUS CARCINOMA BY DIRECT EXTENSION FROM SEROSA
- ADENOMYOSIS

UTERUS, SEROSA, EXCISION

- SEROSAL IMPLANTS OF HIGH GRADE PAPILLARY SEROUS CARCINOMA

SOFT TISSUE, RIGHT URETER, EXCISION

- HIGH GRADE PAPILLARY SEROUS CARCINOMA

OMENTUM, EXCISION

- HIGH GRADE PAPILLARY SEROUS CARCINOMA (12 CM)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

ADIPOSE TISSUE, "SPLENIC," EXCISION
- HIGH GRADE PAPILLARY SEROUS CARCINOMA

SOFT TISSUE, COLONIC WALL, EXCISION
- HIGH GRADE PAPILLARY SEROUS CARCINOMA

ABDOMINAL WALL, LEFT, EXCISION
- HIGH GRADE SEROUS PAPILLARY CARCINOMA, INVOLVING SKELETAL MUSCLE

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen 'omentum biopsy' consisting of an irregularly shaped piece of firm red to yellow-tan tissue measuring 6 x 4 x 2 cm. Sectioned to show firm, off-white cut surface suspicious for metastatic carcinoma. Section frozen as FS1, remainder for permanents," by

Microscopic Description and Comment:

In light of the previous endometrial biopsy showing high grade adenocarcinoma additional sections of the endometrium were taken. All sections of the endometrium demonstrate atypia and curetage effect. After viewing the previous biopsy, the high grade carcinoma seen is consistent with the current primary ovarian serous carcinoma. Therefore, the tumor in the previous biopsy represented retrograde flow of ovarian serous carcinoma and not an endometrial primary carcinoma.

History:

Specimen(s) Received:

A: OMENTUM
B: LEFT TUBE AND LEFT OVARY
C: RIGHT ADNEXA
D: CERVIX AND UTERUS
E: RIGHT URETERAL IMPLANT
F: OMENTUM
G: SPLENIC METASTASES
H: COLONIC EPIPLOICAE WALL
I: LEFT ABDOMINAL WALL NODULE

Gross Description:

The specimens are received in nine formalin-filled containers, all labeled . The first container is labeled . It holds a cassette labeled FS1 containing a piece of tan-yellow tissue measuring

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

2.2 x 1.6 x 0.2 cm. Labeled A1 (FS1). Also in the container are two pieces of omentum measuring 5.0 x 4.5 x 1.5 cm in aggregate. It is sectioned to show firm, white-tan tissue interspersed with fibrofatty tissue. [REDACTED]

The second container is labeled "left tube and ovary." It holds an adnexal structure with a fallopian tube measuring 4.5 x 0.8 x 0.8 cm with numerous nodules along the paratubal soft tissue and unremarkable fimbria. The ovary measures 6.0 x 4.5 x 4.0 cm with an irregular tan-brown nodular surface grossly consistent with surface implants. The fallopian tube is sectioned to show a pinpoint lumen. The ovary is sectioned to show a multiloculated cyst with serosanguineous fluid. A solid area within the cyst is a white-tan firm solid area measuring 3.5 x 2.5 x 2.0 cm, an additional firm area is located attached to the outer surface of the cyst and measures 2.5 x 2.5 x 2.5 cm. Papillary excrescences are also identified along the inner lining of the cyst wall. Labeled B1 - ovarian surface solid lesion; B2 to B5 - solid areas with papillary excrescences; [REDACTED]

The third container is labeled "right adnexa." It holds an adnexal structure with a fallopian tube measuring 4.5 x 1.0 x 1.0 cm with numerous tan nodules on a paratubal soft tissue and unremarkable fimbria. The ovary measures 9.5 x 7.0 x 7.0 cm and has multiple tan-brown, velvety lesions on its surface. The fallopian tube is sectioned to show a pinpoint lumen. The ovary is opened to show an inner cyst lining with multiple tan, velvety papillary excrescences and a solid region measuring 4.5 x 4.0 x 3.5 cm. Labeled C1 - ovary with surface nodules; C2 to C8 - additional sections of ovary with solid areas and papillary excrescences; [REDACTED]

The fourth container is labeled "cervix and uterus." It holds a previously opened uterus measuring 8.0 x 4.5 x 3.5 cm with a tan-brown serosal surface with multiple velvety brown nodules. The 3.5 x 3.5 cm tan ectocervix is unremarkable. The 2.5 x 0.5 cm endocervical canal is tan-brown and unremarkable. The 3.5 x 1.5 cm endometrium is tan-brown and unremarkable. [REDACTED]

The fifth container is labeled "right ureteral implant." It holds a piece of firm fibrofatty tissue measuring 3.0 x 3.0 x 0.8 cm. It is sectioned to show firm, white -tan tissue interspersed with fibrofatty tissue. [REDACTED]

The sixth container is labeled "omentum." It holds numerous (approximately ten) pieces of omentum measuring 30 x 15 x 3 cm in aggregate. The omentum is sectioned to show multiple firm, white-tan nodules scattered throughout the tissue. The largest nodule measures 12 x 10 x 3 cm. [REDACTED]

The seventh container is labeled "splenic metastasis." It holds a piece of fibrofatty tissue measuring 1.6 x 1.2 x 0.3 cm. It is sectioned to show firm, white-tan nodules. [REDACTED]

The eighth container is labeled "colonic epiploicae." It holds two pieces of fibrofatty tissue measuring 4.5 x 3.0 x 1.0 cm and 3.5 x 2.5 x 1.8 cm. The pieces are sectioned to show firm, white-tan nodules on the outer surface of the fatty tissue. [REDACTED]

The ninth container is labeled "left abdominal nodules." It holds two pieces of firm white-tan fibrofatty tissue measuring 2.5 x 1.5 x 1.0 cm and 3.5 x 2.5 x 1.5 cm. They are sectioned to show a firm white-tan cut surface. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

[page 4 of 4]
TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present
Metastatic involvement of the extrapelvic peritoneum is present
Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 65e2fdaf-14ab-40a9-afb0-05707dc00059 (TCGA-24-1417.4058A172-A0F6-4C91-9C79-AAB63525340F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).